TCGA case TCGA-31-1959 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Imperial College. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/186d40cd-624c-4016-a497-b30c892d393c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 50.0 years (18,247 days); Year of diagnosis: 2009; Method of diagnosis: Excisional Biopsy; FIGO stage: Stage IV; Tumor grade: G2; Prior treatment: No; Days to last follow up: 67 days.
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 67 days; Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-31-1959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-31-1959-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 2.
  Slide TCGA-31-1959-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 37; Percent lymphocyte infiltration: 2.
- Sample TCGA-31-1959-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Paciltaxel.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 67 days; disease-specific survival: no event (censored), 67 days; progression-free interval: no event (censored), 67 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-31-1959-01A-01D-0648-01): tumor purity 0.66, ploidy 1.58, whole-genome doublings 0.
